Somatic mutation profile of tumor specimen ALCH-B01L-TTP1-A (aliquot ALCH-B01L-TTP1-A-1-0-D-A657-36) from ALCHEMIST case ALCH-B01L, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.4 years (24,241 days).
Specimen ALCH-B01L-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ac21394c-024b-4f49-b3b8-d0dacb4a3fda.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B01L-NB1-A (Blood Derived Normal), aliquot ALCH-B01L-NB1-A-1-0-D-A658-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7cf99ae5-796d-42cd-9902-075d9465154b

The open-access MAF lists 42 somatic variants for this specimen: 26 protein-altering or splice-affecting, 11 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 11, Intron 3, Splice Site 2, RNA 1, Nonsense Mutation 1, 3'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 62/372 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- BNIP2 | c.845C>T p.A282V | Missense Mutation (SNP) | VAF 16/426 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.449); catalogued as rs1394394468; called by muse, mutect2
- KMT2C | c.11665A>T p.K3889* | Nonsense Mutation (SNP) | VAF 27/222 reads (12%) | catalogued as COSV51465354; called by muse, mutect2, varscan2
- KNL1 | c.3229C>G p.P1077A (on ENST00000346991 / NM_170589.5; = p.P1051A on NM_144508.5) | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV61159509; called by muse, mutect2, varscan2
- POR | c.1321C>T p.R441W | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs782215859; called by muse, mutect2, varscan2
- RXFP1 | c.70G>A p.D24N | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV57048539; called by muse, mutect2
- SLC24A2 | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 52/382 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); catalogued as rs757988035, COSV53862991; called by muse, mutect2, varscan2
- AC092718.8 | c.400G>C p.V134L | Missense Mutation (SNP) | VAF 96/561 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- AS3MT | c.275T>C p.V92A | Missense Mutation (SNP) | VAF 26/250 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); called by muse, mutect2
- ASH1L | c.1711C>T p.P571S | Missense Mutation (SNP) | VAF 16/512 reads (3%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.001); called by muse, mutect2
- ATP1A3 | c.1175C>T p.A392V (on ENST00000545399 / NM_001256214.2; = p.A379V on NM_152296.5) | Missense Mutation (SNP) | VAF 7/165 reads (4%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.614); called by muse, mutect2
- BMI1 | c.869C>T p.S290F | Missense Mutation (SNP) | VAF 44/377 reads (12%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.233); called by muse, mutect2, varscan2
- CNTNAP4 | c.2869G>T p.G957C | Missense Mutation (SNP) | VAF 16/366 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CSMD3 | c.6088C>A p.Q2030K (on ENST00000297405 / NM_001363185.1; = p.Q1926K on NM_052900.3) | Missense Mutation (SNP) | VAF 46/504 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.309); called by muse, mutect2
- CTRC | c.336A>T p.R112S | Missense Mutation (SNP) | VAF 22/278 reads (8%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2
- FRMD4A | c.442-2A>G p.X148_splice | Splice Site (SNP) | VAF 35/327 reads (11%) | called by muse, mutect2, varscan2
- KIF22 | c.1678-2A>G p.X560_splice | Splice Site (SNP) | VAF 5/32 reads (16%) | called by muse, mutect2, varscan2
- LRR1 | c.897G>T p.L299F | Missense Mutation (SNP) | VAF 26/316 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- LRRTM1 | c.1334T>C p.V445A | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.106); called by muse, mutect2
- MYO7A | c.727T>G p.C243G | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2
- PGS1 | c.1072A>C p.K358Q | Missense Mutation (SNP) | VAF 38/273 reads (14%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- PPRC1 | c.1369C>G p.R457G | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- SSH2 | c.3088_3090del p.I1030del | In Frame Del (DEL) | VAF 17/132 reads (13%) | called by mutect2, pindel, varscan2
- SUPT5H | c.1937C>T p.A646V | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.021); called by muse, varscan2
- UTRN | c.4847A>T p.E1616V | Missense Mutation (SNP) | VAF 15/196 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.013); called by muse, mutect2
- WDCP | c.964G>T p.V322L | Missense Mutation (SNP) | VAF 20/340 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.134); called by muse, mutect2
- DCAF6 | c.612A>G p.P204= | Silent (SNP) | VAF 44/367 reads (12%) | catalogued as rs781021091; called by muse, mutect2, varscan2
- FLT1 | c.3942G>T p.L1314= | Silent (SNP) | VAF 11/162 reads (7%) | called by muse, mutect2
- HECTD1 | c.525C>G p.G175= | Silent (SNP) | VAF 62/518 reads (12%) | called by muse, mutect2, varscan2
- ITK | c.1563G>A p.P521= | Silent (SNP) | VAF 50/398 reads (13%) | catalogued as rs767821181, COSV70061493; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNB1 | c.1875C>T p.G625= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as COSV65566911, COSV65570834; called by muse, mutect2, varscan2
- KCND3 | c.477C>T p.S159= | Silent (SNP) | VAF 10/69 reads (14%) | called by muse, mutect2, varscan2
- KRTAP9-9 | c.378C>T p.C126= | Silent (SNP) | VAF 28/164 reads (17%) | called by muse, mutect2, varscan2
- MAPKAPK5 | c.1047C>T p.L349= | Silent (SNP) | VAF 23/328 reads (7%) | called by muse, mutect2
- OR2L13 | c.321G>A p.A107= | Silent (SNP) | VAF 40/355 reads (11%) | catalogued as rs754752033; called by muse, mutect2, varscan2
- SPAG16 | c.675G>T p.P225= | Silent (SNP) | VAF 17/196 reads (9%) | catalogued as COSV55989214; called by muse, mutect2
- ZNF292 | c.7075C>T p.L2359= | Silent (SNP) | VAF 19/210 reads (9%) | catalogued as COSV100370140; called by muse, mutect2
- CDK20 | c.*107G>T | 3'UTR (SNP) | VAF 10/61 reads (16%) | called by muse, mutect2, varscan2
- DHX16 | c.1544+824G>A | Intron (SNP) | VAF 31/337 reads (9%) | called by muse, mutect2
- LINC00574 | n.180T>G | RNA (SNP) | VAF 8/80 reads (10%) | called by muse, mutect2
- RABL2A | c.504+18G>A | Intron (SNP) | VAF 3/156 reads (2%) | called by muse, mutect2
- TARS1 | c.330-887C>T | Intron (SNP) | VAF 38/345 reads (11%) | catalogued as rs902251040; called by muse, mutect2, varscan2
